Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RF, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RF-01A (Primary Tumor).

74D-0-3
Oligodendroglioma, grade III
9451/3
Site ^{CSCF} Brain, supratentorial ¹¹⁶⁵
C71.0
^{Path}
④ Brain, temporal lobe
C71.2
QW 10/4/13

Nature of material: Brain

Received on:

Macroscopy:

Cerebral cortex segment weighing 36 grams and measuring 5.2 x 4.5 x 3.5 cm. One of its sides is coated by lightly congested meninge. The other side shows up bloody, brownish, with hemorrhagic areas.

Microscopy:

The histological sections showed neuroepithelial and multinodular malignant neoplasm, composed of rounded and monomorphic nuclei cells, with granular chromatin and with mild hyperchromasia. The cytoplasm is scanty, observing, sometimes, clear perinuclear halos. We also observed some large and eosinophilic cytoplasm cells with minigemistocistic pattern (GFOC). The tumor is infiltrating, undermining the white matter and adjacent neocortex, which are seen outbreaks of neuronal satellitosis. Are seen some secondary Scherer structures and extent of the neoplasm to the adjacent subarachnoid and the Virchow Robin spaces. Are also seen foci of necrosis and dystrophic calcification. The mitotic figures are easily found. Calls attention the presence of dystrophic calcification in the media of some arteries of medium caliber.

Diagnosis:

Biopsy product of the left temporal lesion: anaplastic oligodendroglioma, WHO grade II (9451/3).

Award of 1p/19q deletion analysis:

The hybridizations were performed on 5 micrometers thick sections of formalin-fixed and paraffin-embedded neoplastic tissue (FFPE) in the most representative tumor area with 1p36/1q25 and 19q13/19p13 probe. 100 to 200 were evaluated in each slide cores.

In this case: The ratio of signals from 1p/1q probes was 1.02. The ratio of signals from 19q/19p probes was 0.92. Conclusion: Anaplastic oligodendroglioma, WHO grade III, with no 1p/19q deletion.

PROFESSIONAL PARTICIPANTS OF REPORT

Source: NCI Genomic Data Commons file 5e579f52-7efd-48b8-9674-32bd385efd5b (TCGA-TQ-A7RF.F4103666-DB5D-4286-8769-F51F08D61FBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).